Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OM, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OM-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: F

PROCEDURE: APMT

ADDENDUM REPORT FOLLOWING IMMUNOHISTOCHEMISTRY:

Immunostaining for p16 was performed on a selected block representing the basaloid squamous cell carcinoma. The p16 is negative.

1CD-0-3
carcinoma, squamous cell, basaloid
8083/3
Site: esophageal,
distal third C15.5

PROCEDURE: APDX

Please see previous report for diagnosis which remains unchanged.

for
10/9/12

the signing staff pathologist, have personally examined and interpreted the slides from this case.

"This test was developed and its performance characteristics determined by the [redacted] It has not been cleared or approved by the U.S. Food and Drug Administration. (The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ["CLIA"] as qualified to perform high complexity testing)."

PROCEDURE: SPHS

Source of Specimen: Esophagus. History of esophageal squamous cell carcinoma.
Operative Procedure/Tissue Submitted: Transhiatal esophagectomy/distal esophagus and proximal stomach.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: F

PROCEDURE: SPGD

1. "Distal esophagus and proximal stomach, freeze proximal margin." Received in formalin in a large container is an 8 cm length of esophagus and a 3.5 x 3.5 cm attached segment of proximal stomach with attached 3.5 x 4 x 2.3 cm adipose tissue. Adventitial surface is unremarkable. There is a 0.4 x 0.6 cm nodule in the esophagus, 2 cm from the proximal surgical margin, which is marked with a black suture. A second nodule (0.5 x 0.5 cm) at the same distance from the proximal margin and 0.6 cm from the first nodule. Both nodules are 3.5 cm from the gastroesophageal junction. Please see gross pictures for more details. The segment of esophagus from 0.8 cm proximal to the masses to 1 cm distal to the masses is entirely submitted with longitudinal sections.

1A. Proximal margin. Frozen section control.

1B-F. Circumferential longitudinal sections at area of nodules with larger nodule in 1F.

1G-H. Serial longitudinal sections at level of tumor, with larger nodule in 1G and smaller nodule in 1H.

1I. Gastroesophageal junction.

1J. Lymph nodes.

2. "Cervical esophageal margin." Received in formalin in a small container is a 2.4 x 0.4 x 0.5 cm portion of esophagus. There is a staple line along the long axis. This is removed and the remainder is submitted in 1 cassette.

FROZEN SECTION REPORT

1. Negative.

_____ have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

ESOPHAGUS CARCINOMA

LOCATION: Lower esophagus

SIZE: Largest focus 0.6 cm

HAS IT BEEN TREATED PREOPERATIVELY WITH CHEMO/RADIATION THERAPY: No

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: F

TYPE OF CARCINOMA: Multifocal but with the largest focus being basaloid squamous cell carcinoma

DEPTH OF INVASION: Submucosa

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/3

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

T1b NO

PROCEDURE: SPDX

1-2. Distal esophagus and proximal stomach, resection: Multifocal invasive squamous cell carcinoma, including one basaloid squamous cell carcinoma, which invades into the mid submucosa, arising in a background of extensive high grade squamous dysplasia. Margins negative. Three lymph nodes negative for neoplasm. Please see template for details.

I, [redacted] the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 2101f56d-a39b-4a44-8635-8f49984bace1 (TCGA-L5-A4OM.675BD447-E602-4A16-A546-3B18399905F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).